Gene-level copy-number profile of tumor specimen TCGA-XF-A9SJ-01A from TCGA case TCGA-XF-A9SJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 83.1 years (30,362 days).
Specimen TCGA-XF-A9SJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.bffac7cb-9671-4418-a015-68262a7a9d2c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a892f06-ef25-416b-9e9e-589602224001

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,564; copy number 2: 21,844; copy number 3: 16,902; copy number 4: 11,077; copy number 5: 3,048; copy number 6: 963; copy number 7: 54; copy number 8: 301; copy number 9: 62; copy number 10: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SJ-01A-11D-A390-01): tumor purity 0.56, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,432 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–157,640,301, 656 genes, copy number 5–8 (broad region; genes not listed).
- chr3:8,573,726–21,226,305, 236 genes, copy number 5 (broad region; genes not listed).
- chr3:90,202,316–177,011,067, 1,328 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:177,037,405–177,047,923, 1 gene, copy number 5: TBL1XR1-AS1.
- chr3:187,217,282–192,767,764, 61 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr6:20,212,087–23,972,941, 38 genes, copy number 5: AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1.
- chr8:65,526,738–68,237,032, 49 genes, copy number 6–10 (within-gene range 4–10): LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2.
- chr8:81,149,107–85,284,073, 55 genes, copy number 6–8: AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2.
- chr8:86,180,418–103,501,895, 322 genes, copy number 5–9 (broad region; genes not listed).
- chr8:103,559,099–103,568,978, 2 genes, copy number 5: PTMAP15, AC007751.1.
- chr12:65,758,020–68,971,570, 73 genes, copy number 7–9 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).
- chr21:10,328,411–39,802,096, 525 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,557. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
